Somatic mutation profile of tumor specimen TCGA-BA-A4IG-01A (aliquot TCGA-BA-A4IG-01A-11D-A25Y-08) from TCGA case TCGA-BA-A4IG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G3; Age at diagnosis: 77.8 years (28,402 days).
Specimen TCGA-BA-A4IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f49455-83c6-4be9-ac03-50ffa54b26f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A4IG-10A (Blood Derived Normal), aliquot TCGA-BA-A4IG-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2598a5de-9c1b-4e98-8188-ce0f7dd1e0f1

The open-access MAF lists 139 somatic variants for this specimen: 101 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 34, Nonsense Mutation 9, Frame Shift Del 7, Intron 3, Splice Site 2, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD14A-ACY1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV101352267; called by muse, mutect2, varscan2
- ACTL8 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100958729; called by muse, mutect2, varscan2
- ADGRB3 | c.4249T>A p.S1417T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.275); catalogued as COSV99486232; called by muse, mutect2, varscan2
- ADGRL2 | c.2477A>C p.N826T (on ENST00000370717 / NM_001366005.1; = p.N813T on NM_012302.4) | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54673186, COSV99590431; called by muse, mutect2, varscan2
- AGO4 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100943026; called by muse, mutect2, varscan2
- AL645922.1 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1373937055, COSV100191328; called by muse, mutect2, varscan2
- ALK | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV101202447; called by muse, mutect2
- ALPK2 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as COSV100864585; called by muse, mutect2
- ANGPTL7 | c.716T>A p.V239D | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV100816498; called by muse, mutect2
- ANKLE2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100514264; called by muse, mutect2, varscan2
- ANKLE2 | c.729A>T p.R243S | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100514266; called by muse, mutect2, varscan2
- ANO3 | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373975805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APP | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs1439246491, COSV100696069; called by muse, mutect2, varscan2
- ARHGAP5 | c.1049del p.L350Cfs*4 | Frame Shift Del (DEL) | VAF 57/238 reads (24%) | catalogued as COSV61539599; called by mutect2, pindel, varscan2
- ARMC5 | c.1891G>T p.V631F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99192683; called by muse, mutect2, varscan2
- ASPM | c.5294G>C p.R1765T | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV99660817; called by muse, mutect2, varscan2
- ATP8B1 | c.956T>C p.I319T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99377590; called by muse, mutect2, varscan2
- C1QTNF3 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as rs754470860, COSV51467668; called by muse, mutect2, varscan2
- CCDC191 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55672171; called by muse, mutect2, varscan2
- CCDC39 | c.2098C>G p.Q700E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV99870046; called by muse, mutect2, varscan2
- CCDC42 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99549865; called by muse, mutect2, varscan2
- CDC5L | c.2155A>T p.I719F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV101015117; called by muse, mutect2, varscan2
- CLEC18B | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 23/195 reads (12%) | catalogued as COSV100376044; called by muse, mutect2, varscan2
- CNGB3 | c.1479A>G p.L493= | Splice Region (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100182584; called by muse, mutect2
- CUBN | c.10487C>T p.S3496F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100911957; called by muse, mutect2, varscan2
- CYP4F8 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV100358178; called by muse, mutect2, varscan2
- DCT | c.1526A>G p.H509R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100986264; called by muse, mutect2, varscan2
- DGKB | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99341713; called by muse, mutect2, varscan2
- DOK6 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as COSV101234723; called by muse, mutect2, varscan2
- DOT1L | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.26); catalogued as rs377639105; called by muse, mutect2, varscan2
- EIF2B3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs755510412, COSV100838978; called by muse, mutect2, varscan2
- ERBIN | c.3445A>T p.I1149F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV99397442; called by muse, mutect2, varscan2
- EVA1A | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99285760; called by muse, mutect2, varscan2
- FIGNL1 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs749053157, COSV100794932; called by muse, mutect2, varscan2
- GBP7 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1350951524, COSV54010734; called by muse, mutect2, varscan2
- GRK4 | c.1175A>T p.K392I (on ENST00000398052 / NM_182982.3; = p.K360I on NM_005307.3) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100584188; called by muse, mutect2, varscan2
- HECTD4 | c.5693C>T p.A1898V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV101108097; called by muse, mutect2, varscan2
- HIF1AN | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100142780; called by muse, varscan2
- HIRA | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV99600706; called by muse, mutect2, varscan2
- HNRNPA3 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV101182959; called by muse, mutect2, varscan2
- HS6ST1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1313422880, COSV99389768; called by muse, mutect2
- INPPL1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99996457; called by muse, mutect2, varscan2
- JAK1 | c.2870A>C p.E957A | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100692113; called by muse, mutect2, varscan2
- KCNK15 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.928); catalogued as COSV100865180, COSV65719203; called by muse, mutect2, varscan2
- KIAA0319L | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100357552; called by muse, mutect2
- LRRTM1 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.795); catalogued as COSV99702888, COSV99703135; called by muse, mutect2
- MAP3K9 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV101173711, COSV67122049; called by muse, mutect2, varscan2
- MME | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100852469; called by muse, mutect2
- MRPS15 | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100910771; called by muse, mutect2, varscan2
- MTFR1 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100050308; called by muse, mutect2, varscan2
- NBAS | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs373721233, COSV99870893; called by muse, mutect2, varscan2
- NHLRC1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs796052754, COSV61481567; ClinVar: uncertain significance; called by muse, mutect2
- NTN4 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.027); catalogued as COSV100643826; called by muse, mutect2, varscan2
- OCM | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV99631489; called by muse, mutect2, varscan2
- OTUD6B | c.87A>T p.K29N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV99576020; called by muse, mutect2, varscan2
- PALB2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); catalogued as rs1567221497, COSV55163039, COSV99848316; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARP14 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV71735469; called by muse, mutect2, varscan2
- PEX11G | c.249+2T>G p.X83_splice | Splice Site (SNP) | VAF 7/126 reads (6%) | catalogued as COSV99675897; called by muse, mutect2
- PPP4R1 | c.2308C>G p.L770V (on ENST00000400556 / NM_001042388.3; = p.L753V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV99553790; called by muse, mutect2
- PPP4R4 | c.1026A>T p.K342N | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV100428849; called by muse, mutect2, varscan2
- PRCC | c.988A>G p.S330G | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV99618831; called by muse, mutect2, varscan2
- PTPN12 | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV99949917; called by muse, mutect2, varscan2
- RAPGEF1 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.129); catalogued as rs548185079, COSV100940573; called by muse, mutect2
- RASIP1 | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99710953; called by muse, mutect2, varscan2
- RIC1 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV99317698; called by muse, mutect2
- RIMS4 | c.364G>C p.G122R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV100865181; called by muse, mutect2
- RSRC1 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as COSV99906666; called by muse, mutect2, varscan2
- RUSC2 | c.2061G>C p.Q687H | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100770803; called by muse, mutect2, varscan2
- SEMA3G | c.2175C>A p.Y725* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV99202520; called by muse, mutect2, varscan2
- SEPTIN8 | c.1068G>C p.E356D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99736445; called by muse, mutect2, varscan2
- SLC38A11 | c.271G>C p.E91Q (on ENST00000409149 / NM_001351539.1; = p.E69Q on NM_173512.2) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100366977; called by muse, mutect2
- SMARCD2 | c.1268T>C p.F423S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99856253, COSV99856546; called by muse, mutect2, varscan2
- SP6 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100647065, COSV60617229; called by muse, mutect2, varscan2
- SPEM2 | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100424415; called by muse, mutect2
- SRSF6 | c.345A>T p.E115D | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV99719782; called by muse, mutect2, varscan2
- TGS1 | c.1397G>C p.R466P | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99485568; called by muse, mutect2, varscan2
- TICAM1 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99941189; called by muse, mutect2, varscan2
- TP63 | c.1751T>G p.L584R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM061225, COSV99287929; called by muse, mutect2
- TRIM59 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs779124243, COSV59086784; called by muse, mutect2, varscan2
- TTN | c.87575C>T p.T29192I (on ENST00000591111; = p.T21768I on NM_003319.4) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | PolyPhen possibly damaging (0.857); catalogued as rs727505334, COSV100622100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR44 | c.1367G>C p.S456T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV99561775; called by mutect2, varscan2
- ZNF233 | c.1705T>C p.C569R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323596302, COSV100492382; called by muse, mutect2
- ZNF334 | c.1020C>G p.F340L | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV100749150; called by muse, mutect2
- ZNF335 | c.2897G>A p.G966E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100533228; called by muse, varscan2
- ZNF358 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99900736; called by muse, varscan2
- ZNF44 | c.1150C>G p.P384A (on ENST00000356109 / NM_001164276.2; = p.P336A on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100633634; called by muse, mutect2, varscan2
- ZNF551 | c.1341T>A p.Y447* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV99990147; called by muse, mutect2, varscan2
- ZNF558 | c.449A>T p.K150I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100037993; called by muse, mutect2, varscan2
- ZNF600 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 109/350 reads (31%) | catalogued as rs1223124075, COSV100593053; called by muse, mutect2, varscan2
- ADCY3 | c.1791_1805+20del p.X597_splice | Splice Site (DEL) | VAF 5/61 reads (8%) | called by mutect2, pindel
- ADNP2 | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- BRCA1 | c.147_155del p.K50_L52del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CHML | c.688_698del p.N230Gfs*13 | Frame Shift Del (DEL) | VAF 51/172 reads (30%) | called by mutect2, pindel, varscan2
- CRISPLD2 | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- DNAJC13 | c.6615del p.Y2206Tfs*27 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- IGKV5-2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MACF1 | c.10272_10296del p.S3424Rfs*15 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- OBSCN | c.20193del p.F6732Sfs*20 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- POTEA | c.1112G>C p.G371A (on ENST00000519951 / NM_001005365.2; = p.G325A on NM_001002920.1) | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PUS10 | c.1138del p.I380Lfs*21 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- UBAP2 | c.1573_1576del p.G525Qfs*7 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- ABCC11 | c.570A>G p.E190= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100750986; called by muse, mutect2, varscan2
- AC097637.1 | c.402C>T p.S134= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV59726676; called by muse, mutect2, varscan2
- ALPK3 | c.1974G>A p.Q658= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99360294; called by muse, mutect2
- ARHGEF3 | c.1164C>T p.D388= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99575657; called by muse, mutect2, varscan2
- ARID2 | c.3519C>A p.T1173= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100536617; called by muse, mutect2
- ATAD2 | c.3450G>A p.P1150= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs147456124; called by muse, mutect2, varscan2
- BCAR1 | c.2472C>A p.R824= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99366978; called by muse, mutect2, varscan2
- DOP1A | c.267T>A p.I89= | Silent (SNP) | VAF 9/264 reads (3%) | called by muse, mutect2
- ERGIC2 | c.360G>A p.Q120= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV100792015; called by muse, mutect2, varscan2
- KIF5C | c.894C>A p.T298= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101276176; called by muse, mutect2, varscan2
- MYH10 | c.5424C>A p.V1808= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99345869; called by muse, mutect2, varscan2
- MYO3A | c.4221G>A p.K1407= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV56327091, COSV99780686; called by muse, mutect2, varscan2
- NFATC3 | c.765G>T p.L255= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV100285470; called by muse, mutect2
- NUBP2 | c.765C>A p.L255= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99236615; called by muse, mutect2
- NUP155 | c.387G>A p.E129= (on ENST00000231498 / NM_153485.3; = p.E70= on NM_004298.4) | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV99193945; called by muse, mutect2, varscan2
- OR4M1 | c.618C>A p.I206= | Silent (SNP) | VAF 23/370 reads (6%) | catalogued as rs1315723786, COSV60063427, COSV60063764; called by muse, mutect2
- OR6B3 | c.387G>A p.P129= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs776979729, COSV100097485; called by muse, mutect2, varscan2
- PARPBP | c.714T>C p.Y238= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV100569260; called by muse, mutect2
- PBDC1 | c.285A>G p.E95= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100972849; called by muse, mutect2, varscan2
- PBX4 | c.858G>A p.T286= | Silent (SNP) | VAF 23/298 reads (8%) | catalogued as rs200643734, COSV99232370; called by muse, mutect2
- RANBP2 | c.5601A>G p.E1867= | Silent (SNP) | VAF 83/297 reads (28%) | catalogued as COSV99312766; called by muse, mutect2, varscan2
- RHOBTB2 | c.456C>T p.V152= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as COSV99311140; called by muse, mutect2
- SHOC1 | c.1038A>T p.I346= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV100597863; called by muse, mutect2, varscan2
- SLC2A3 | c.1041G>C p.T347= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs760682928, COSV99306828; called by muse, mutect2, varscan2
- SURF2 | c.699C>G p.G233= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100914371; called by muse, mutect2
- TMC8 | c.1323C>T p.F441= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs529856329, COSV59211951; called by muse, mutect2, varscan2
- TMCO3 | c.321A>G p.E107= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100952375; called by muse, mutect2, varscan2
- TMPRSS11B | c.618C>T p.G206= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV60291707; called by muse, mutect2, varscan2
- TREM2 | c.30C>G p.L10= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100632666; called by muse, mutect2, varscan2
- TTN | c.18297G>T p.V6099= (on ENST00000591111; = p.V5172= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100622102; called by muse, mutect2, varscan2
- VNN1 | c.606C>A p.T202= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV100907787, COSV63389594; called by muse, mutect2
- VPS13B | c.7233C>T p.I2411= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100662774; called by muse, mutect2
- ZC3H4 | c.1101C>T p.D367= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as COSV99452586; called by muse, mutect2
- ZNF608 | c.2592G>T p.L864= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100102146; called by muse, mutect2, varscan2
- EIF6 | c.107+40G>C | Intron (SNP) | VAF 22/134 reads (16%) | catalogued as COSV100981625; called by muse, mutect2, varscan2
- RNF213 | c.3024+111A>T | Intron (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100173749; called by muse, mutect2, varscan2
- RPL13A | c.402+159G>C | Intron (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100768885; called by muse, mutect2, varscan2
- TXLNGY | n.4652A>T | RNA (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
